TCGA case TCGA-19-1387 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Case Western. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2f8b698a-cbd0-4cab-a814-dc683e0e9305

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 81 years; Vital status: Alive.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 81.8 years (29,892 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 19 days; Days to treatment end: 58 days; Treatment dose: 6,000 cGy; Chemo concurrent to radiation: Yes; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 19 days; Days to treatment end: 58 days; Number of cycles: 1; Treatment dose: 5,600 mg; Route of administration: Oral.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 82.1 years (29,971 days); Days to diagnosis: 79 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 79 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 79 days.
- Days to follow up: 181 days; Disease response: With Tumor.
- Karnofsky performance status: 60; Timepoint: Post Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-19-1387-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.4; Shortest dimension: 0.4.
  Slide TCGA-19-1387-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 30; Percent stromal cells: 0.
  Slide TCGA-19-1387-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50.
- Sample TCGA-19-1387-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-19-1387-10C: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment: Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Concurrent.
- Drug treatment, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 181 days; disease-specific survival: no event (censored), 181 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 79 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-19-1387-01A-01D-0591-01): tumor purity 0.82, ploidy 2.05, whole-genome doublings 0.
